Somatic mutation profile of tumor specimen TCGA-13-1477-01A (aliquot TCGA-13-1477-01A-01D-0472-01) from TCGA case TCGA-13-1477, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 49.6 years (18,111 days).
Specimen TCGA-13-1477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e76270-284e-4817-ba51-769bdb077477.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1477-10A (Blood Derived Normal), aliquot TCGA-13-1477-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04f77e65-97c6-45d5-81af-82b7ab6426e4

The open-access MAF lists 173 somatic variants for this specimen: 129 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 39, Nonsense Mutation 12, Frame Shift Ins 9, Splice Site 3, Intron 3, RNA 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99517380; called by muse, mutect2, varscan2
- AGBL5 | c.2299G>T p.G767W | Missense Mutation (SNP) | VAF 138/394 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64079938; called by muse, varscan2
- ANKRD40 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53334552; called by muse, mutect2
- ARFGEF2 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100904063, COSV64214145; called by muse, mutect2
- ARHGAP30 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs202221316, COSV63517278; called by muse, mutect2, varscan2
- ARHGEF2 | c.982G>A p.G328S (on ENST00000361247 / NM_001162383.2; = p.G300S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100560133; called by muse, mutect2
- ARID1B | c.4309G>A p.G1437S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.019); catalogued as rs376207220, COSV51666946; called by mutect2, varscan2
- ATP1A4 | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100927451; called by muse, mutect2
- ATP2B1 | c.2336-1G>A p.X779_splice | Splice Site (SNP) | VAF 13/303 reads (4%) | catalogued as COSV99665262; called by muse, mutect2
- BRD2 | c.2204A>G p.E735G | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100875579; called by muse, mutect2
- BST1 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV99399811; called by muse, mutect2
- C2 | c.740T>A p.I247N | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100190721; called by muse, mutect2
- C6orf136 | c.865G>A p.V289M (on ENST00000376473 / NM_001109938.3; = p.V155M on NM_145029.4) | Missense Mutation (SNP) | VAF 99/141 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53314751; called by muse, mutect2, varscan2
- CABP4 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100351441; called by muse, mutect2
- CCDC81 | c.667C>T p.P223S (on ENST00000445632 / NM_001156474.2; = p.P133S on NM_021827.4) | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99563990; called by muse, mutect2
- CHCHD5 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 9/255 reads (4%) | catalogued as COSV100260786; called by muse, mutect2
- CHRNB3 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs745784162, COSV51495696; called by muse, mutect2, varscan2
- CLPB | c.216dup p.R73Afs*120 | Frame Shift Ins (INS) | VAF 11/100 reads (11%) | catalogued as rs752731849; called by pindel, varscan2
- CRB1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 17/538 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV66336508; called by muse, mutect2
- CREBBP | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99268829; called by muse, mutect2
- DDIAS | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 16/420 reads (4%) | catalogued as COSV100231048, COSV61271407, COSV61272041; called by muse, mutect2
- DDIT4 | c.433dup p.A145Gfs*50 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | catalogued as rs773055234; called by mutect2, pindel, varscan2
- DECR1 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 50/696 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99616044; called by muse, mutect2
- DENND2B | c.3268G>C p.E1090Q | Missense Mutation (SNP) | VAF 64/712 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV58204905; called by muse, mutect2
- DIAPH1 | c.2392T>C p.W798R | Missense Mutation (SNP) | VAF 20/676 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525972; called by muse, mutect2
- DIPK2A | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs758969218, COSV59857702; called by muse, mutect2, varscan2
- DOP1B | c.2723C>T p.T908M | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs541281990, COSV67693851; called by muse, mutect2, varscan2
- DSCAML1 | c.2680G>A p.V894I (on ENST00000321322; = p.V834I on NM_020693.4) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs768108077, COSV58381625; called by muse, mutect2, varscan2
- DSP | c.3749A>T p.K1250M | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV101131189; called by muse, mutect2
- DYSF | c.5801A>G p.K1934R | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99244833; called by muse, mutect2
- EDRF1 | c.2135C>T p.A712V (on ENST00000356792 / NM_001202438.2; = p.A678V on NM_015608.2) | Missense Mutation (SNP) | VAF 129/535 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61764709; called by muse, mutect2, varscan2
- EGLN1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 10/204 reads (5%) | catalogued as CM163980, COSV100791213; called by muse, mutect2
- EIF1AD | c.171C>A p.Y57* | Nonsense Mutation (SNP) | VAF 25/378 reads (7%) | catalogued as COSV100381342; called by muse, mutect2
- EIF2AK3 | c.1885A>T p.R629W | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303525; called by muse, mutect2
- ENPP4 | c.791A>C p.D264A | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58089221; called by muse, mutect2, varscan2
- EPHA7 | c.2952G>A p.M984I | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs1418929572, COSV100993352; called by muse, mutect2
- ERCC6 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100875731, COSV63390066; called by muse, mutect2
- FAT1 | c.7430A>G p.Q2477R | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV101499131; called by muse, mutect2
- FAT4 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV101271808; called by muse, mutect2
- FCN2 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52477443; called by muse, mutect2, varscan2
- FGD3 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.26); catalogued as COSV61598200; called by muse, mutect2
- FGR | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100925773; called by muse, mutect2
- FMR1NB | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 37/908 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs193228973, COSV100975489; called by muse, mutect2
- FNDC3B | c.2906C>A p.A969D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV61040048, COSV61044282; called by muse, mutect2, varscan2
- GABBR1 | c.2838dup p.D947Rfs*4 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs759362541; called by mutect2, pindel
- GMPS | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99902931; called by muse, mutect2
- GPM6B | c.720G>T p.L240= | Splice Region (SNP) | VAF 28/300 reads (9%) | catalogued as COSV57423060; called by muse, mutect2
- GSTM1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564396; called by muse, mutect2
- HJURP | c.472_495+4del p.X158_splice | Splice Site (DEL) | VAF 22/66 reads (33%) | catalogued as COSV64978974; called by mutect2, pindel
- HRH4 | c.868A>T p.R290W | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99907736; called by muse, mutect2
- IFIT2 | c.192A>T p.K64N | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.322); catalogued as COSV99259941; called by muse, mutect2
- IGFN1 | c.2871G>T p.L957F (on ENST00000295591 / NM_001367841.1; = p.L3414F on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99811307; called by muse, mutect2
- IL12RB2 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV52021231; called by muse, mutect2
- INTS3 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100015710; called by muse, mutect2
- IRF1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810412; called by muse, mutect2
- ITM2C | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV58399683; called by muse, mutect2, varscan2
- KCNN3 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99677573; called by muse, mutect2
- KDSR | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458993937, COSV100430173; called by muse, mutect2
- KRT40 | c.152G>T p.R51M | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV100898791; called by muse, mutect2
- LIFR | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs773625392, COSV54692478; called by muse, mutect2, varscan2
- LINGO2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as rs1040309410, COSV58064985; called by muse, mutect2
- LRP12 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.115); catalogued as COSV52629394; called by muse, mutect2
- LRP2 | c.3853C>A p.H1285N | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV99786822; called by muse, mutect2
- LY6G6F-LY6G6D | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); catalogued as COSV101012183; called by muse, mutect2
- MCTP2 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265933738, COSV100537258; called by muse, mutect2
- MGAT5 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56097932, COSV99924169; called by muse, mutect2
- MITD1 | c.391-1G>A p.X131_splice | Splice Site (SNP) | VAF 6/144 reads (4%) | catalogued as COSV99175544; called by muse, mutect2
- MORC2 | c.976C>T p.R326W (on ENST00000397641 / NM_001303256.3; = p.R264W on NM_014941.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs558057376, COSV99309572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPDZ | c.5395G>T p.V1799L (on ENST00000319217 / NM_001330637.2; = p.V1766L on NM_001261406.2 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100056260; called by muse, mutect2, varscan2
- MYL4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs111293783; called by muse, mutect2, varscan2
- NDN | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV100086260; called by muse, mutect2, varscan2
- NEUROD6 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99773870; called by muse, mutect2
- NLGN3 | c.2392C>T p.R798C (on ENST00000358741 / NM_181303.2; = p.R778C on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1445089858, COSV62442724; called by muse, mutect2, varscan2
- NYNRIN | c.4069G>A p.A1357T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV101230518; called by muse, mutect2
- OR52W1 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100258602; called by muse, mutect2
- OR7D4 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 12/270 reads (4%) | catalogued as COSV100432613, COSV58071162; called by muse, mutect2
- PALB2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 34/231 reads (15%) | catalogued as COSV55166412; called by muse, mutect2, varscan2
- PCDHA10 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.223); catalogued as COSV100248179; called by muse, mutect2
- PCDHB13 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 66/805 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); catalogued as rs782153485, COSV53397876; called by muse, mutect2
- PDZRN3 | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 48/1336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99727838; called by muse, mutect2
- PFKFB4 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 40/640 reads (6%) | PolyPhen benign (0.005); catalogued as rs767015937, COSV99219383; called by muse, mutect2
- PIGB | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99380094; called by muse, mutect2
- PKHD1 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 18/524 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100581517; called by muse, mutect2
- PLAAT5 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 21/516 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100080362; called by muse, mutect2
- PRKDC | c.8881G>A p.A2961T | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV100038768; called by muse, mutect2
- PSG4 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.297); catalogued as rs1228508616, COSV99736430; called by muse, mutect2
- PTPRT | c.2435G>A p.S812N | Missense Mutation (SNP) | VAF 42/1238 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100625645; called by muse, mutect2
- RBL2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1303305126, COSV100043359, COSV100043376; called by muse, mutect2
- RBM24 | c.482C>A p.S161* (on ENST00000379052 / NM_001143942.2; = p.S116* on NM_153020.2) | Nonsense Mutation (SNP) | VAF 14/171 reads (8%) | catalogued as rs745812959, COSV100552854; called by muse, mutect2
- RNASE3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs779933714, COSV58959571; called by muse, mutect2
- RPTOR | c.641A>G p.E214G | Missense Mutation (SNP) | VAF 26/535 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV100155357; called by muse, mutect2
- SATB1 | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100112963; called by muse, mutect2
- SETBP1 | c.1950G>T p.K650N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV99952285; called by muse, mutect2
- SH2D2A | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 40/880 reads (5%) | catalogued as rs1466898949, COSV100949041; called by muse, mutect2
- SLC16A4 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100872911; called by muse, mutect2
- SLITRK6 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101233186; called by muse, mutect2
- SPAG17 | c.4573C>G p.Q1525E | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100308197; called by muse, mutect2
- SPATA25 | c.536G>A p.W179* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs146844243; called by mutect2, varscan2
- SPATA32 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100077372; called by muse, mutect2
- TASOR2 | c.3679G>A p.G1227R | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60168094; called by muse, mutect2, varscan2
- TBC1D4 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | catalogued as COSV100884538; called by muse, mutect2
- TECTA | c.2299_2300insA p.R767Qfs*92 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as COSV99878868; called by mutect2, pindel, varscan2
- THAP9 | c.1421A>G p.K474R | Missense Mutation (SNP) | VAF 26/774 reads (3%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.628); catalogued as COSV100155755; called by muse, mutect2
- THBS2 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827657; called by muse, mutect2
- TLN2 | c.4930G>A p.D1644N | Missense Mutation (SNP) | VAF 60/732 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750169478, COSV60889329; called by muse, mutect2
- TNN | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV53428821; called by muse, mutect2, varscan2
- TNP1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1415906776, COSV99378479; called by muse, mutect2
- UGT2B17 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 19/762 reads (2%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as rs1239824381, COSV58501875; called by muse, mutect2
- UNC13A | c.2824A>T p.N942Y | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53199244; called by muse, mutect2, varscan2
- USP26 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 31/980 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100896556; called by muse, mutect2
- USP37 | c.689A>T p.K230M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV51444413; called by muse, mutect2, varscan2
- VPS54 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV55440880, COSV55441969; called by muse, mutect2, varscan2
- VRTN | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs756291711, COSV56439091; called by muse, mutect2, varscan2
- ZNF234 | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as COSV70603473; called by muse, mutect2
- ZNF45 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | catalogued as COSV99524047; called by muse, mutect2
- ZNF518A | c.1767G>T p.E589D | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100283371; called by muse, mutect2
- ZXDB | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100885805; called by muse, mutect2
- ANKLE2 | c.1678dup p.R560Kfs*4 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- ANKRA2 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- GBA3 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GBP6 | c.1035dup p.T346Hfs*15 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- GRN | c.559dup p.L187Pfs*11 | Frame Shift Ins (INS) | VAF 37/181 reads (20%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 10/317 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.165); called by muse, mutect2
- KDM4A | c.1813dup p.R605Pfs*13 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- OVCH2 | c.857A>T p.D286V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SCN5A | c.4445dup p.Q1483Pfs*49 (on ENST00000333535 / NM_198056.3; = p.Q1482Pfs*49 on NM_000335.5) | Frame Shift Ins (INS) | VAF 22/245 reads (9%) | called by mutect2, pindel
- SYNE2 | c.941_949del p.Q314_L316del | In Frame Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- USP39 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 12/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR25 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- ABHD6 | c.354C>T p.D118= | Silent (SNP) | VAF 8/221 reads (4%) | catalogued as COSV99916916; called by muse, mutect2
- ADCY1 | c.2265G>A p.L755= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV99811402; called by muse, mutect2
- AMOT | c.2349G>A p.R783= (on ENST00000371959 / NM_001113490.1; = p.R374= on NM_133265.3) | Silent (SNP) | VAF 36/1082 reads (3%) | catalogued as COSV100494789; called by muse, mutect2
- BCORL1 | c.690A>G p.P230= | Silent (SNP) | VAF 46/541 reads (9%) | catalogued as COSV54399011; called by muse, mutect2
- CD8A | c.663G>T p.V221= | Silent (SNP) | VAF 16/343 reads (5%) | catalogued as COSV99374241; called by muse, mutect2
- CERS4 | c.6G>A p.L2= | Silent (SNP) | VAF 94/379 reads (25%) | catalogued as COSV52167896; called by muse, mutect2, varscan2
- CNTD1 | c.6C>T p.D2= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs762595375, COSV55906302; called by muse, mutect2, varscan2
- COL12A1 | c.4929T>A p.S1643= | Silent (SNP) | VAF 28/744 reads (4%) | catalogued as COSV100485498; called by muse, mutect2
- CREBBP | c.1212C>T p.C404= | Silent (SNP) | VAF 17/394 reads (4%) | catalogued as COSV99268833; called by muse, mutect2
- DGKD | c.1743C>A p.G581= (on ENST00000264057 / NM_152879.3; = p.G537= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99895574; called by muse, mutect2
- DPP6 | c.1653G>A p.L551= (on ENST00000377770 / NM_001364500.2; = p.L489= on NM_001936.5) | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as COSV100123520; called by muse, mutect2
- EIF4A1 | c.432G>A p.V144= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs1332269258, COSV51511221; called by muse, mutect2, varscan2
- FCRL5 | c.813T>C p.S271= | Silent (SNP) | VAF 20/584 reads (3%) | catalogued as COSV100708593; called by muse, mutect2
- GYS1 | c.1239T>C p.L413= | Silent (SNP) | VAF 20/373 reads (5%) | catalogued as COSV99620500; called by muse, mutect2
- IYD | c.666C>T p.G222= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99989356; called by muse, mutect2
- KCNV2 | c.1089C>T p.G363= | Silent (SNP) | VAF 13/281 reads (5%) | catalogued as COSV101172524; called by muse, mutect2
- LHX4 | c.1044A>G p.V348= | Silent (SNP) | VAF 74/1294 reads (6%) | catalogued as rs1034167464, COSV99761223; called by muse, mutect2
- LVRN | c.291C>T p.R97= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV100773356, COSV100773438; called by muse, mutect2
- LYSMD1 | c.576G>A p.L192= | Silent (SNP) | VAF 36/714 reads (5%) | catalogued as COSV100925297; called by muse, mutect2
- MAGEB1 | c.771C>T p.Y257= | Silent (SNP) | VAF 45/225 reads (20%) | catalogued as rs766373792, COSV66775251, COSV66775580; called by muse, mutect2, varscan2
- MARK2 | c.180C>A p.G60= | Silent (SNP) | VAF 11/269 reads (4%) | catalogued as COSV100158174; called by muse, mutect2
- MBD3 | c.240C>T p.R80= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs897402816, COSV99337049; called by muse, mutect2
- MUC16 | c.29784C>G p.S9928= | Silent (SNP) | VAF 57/535 reads (11%) | catalogued as COSV67474976; called by muse, mutect2, varscan2
- MYO18A | c.3838C>T p.L1280= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100571975; called by muse, mutect2
- NLRP4 | c.264C>T p.V88= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV100015734; called by muse, mutect2
- NOP2 | c.2073G>A p.E691= (on ENST00000322166 / NM_001258308.2; = p.E687= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/358 reads (6%) | catalogued as rs369192791; called by muse, mutect2
- PCDH12 | c.1956T>C p.H652= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV99186028; called by muse, mutect2
- PLAC1 | c.130C>T p.L44= | Silent (SNP) | VAF 19/667 reads (3%) | catalogued as COSV100821483; called by muse, mutect2
- POP1 | c.2502C>T p.G834= | Silent (SNP) | VAF 11/316 reads (3%) | called by muse, mutect2
- RSPH4A | c.1650T>C p.H550= | Silent (SNP) | VAF 229/401 reads (57%) | catalogued as rs1344288902, COSV99993963; called by muse, mutect2, varscan2
- RYR2 | c.201T>C p.F67= | Silent (SNP) | VAF 99/371 reads (27%) | catalogued as COSV63692446; called by muse, mutect2, varscan2
- SHROOM4 | c.3846C>T p.A1282= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as COSV99173060; called by muse, mutect2
- SPTA1 | c.442C>T p.L148= | Silent (SNP) | VAF 18/626 reads (3%) | catalogued as COSV100934454, COSV100934868; called by muse, mutect2
- STRN4 | c.870G>A p.Q290= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs1280068536, COSV99623376; called by muse, mutect2
- USP42 | c.1812G>A p.L604= | Silent (SNP) | VAF 91/102 reads (89%) | catalogued as COSV60361379; called by muse, mutect2, varscan2
- USP43 | c.2247G>C p.L749= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99556440; called by mutect2, varscan2
- ZIC3 | c.63G>A p.A21= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54975067; called by muse, mutect2, varscan2
- ZNF287 | c.1053T>C p.H351= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as COSV101209334; called by muse, mutect2
- ZNF543 | c.135C>T p.L45= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as COSV100386661; called by muse, mutect2
- ACOX1 | c.431-2742C>A | Intron (SNP) | VAF 22/266 reads (8%) | catalogued as COSV53133905; called by muse, mutect2
- AL136982.4 | n.447C>T | RNA (SNP) | VAF 28/872 reads (3%) | called by muse, mutect2
- FAM184A | c.1815+381C>G | Intron (SNP) | VAF 44/68 reads (65%) | catalogued as COSV100137448; called by muse, mutect2
- MIR505 | n.4G>A | RNA (SNP) | VAF 11/330 reads (3%) | catalogued as COSV100990115; called by muse, mutect2
- SON | c.6657+312T>C | Intron (SNP) | VAF 12/267 reads (4%) | catalogued as COSV99277096; called by muse, mutect2
